Somatic mutation profile of tumor specimen TCGA-DJ-A2Q3-01A (aliquot TCGA-DJ-A2Q3-01A-11D-A18F-08) from TCGA case TCGA-DJ-A2Q3, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 62.0 years (22,637 days).
Specimen TCGA-DJ-A2Q3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e8b54c6-6b86-48c2-9b62-35a2a181c378.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A2Q3-10A (Blood Derived Normal), aliquot TCGA-DJ-A2Q3-10A-01D-A18F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0edec2ef-a2d5-41bf-af96-7d38598f0530

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 9, Silent 2, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACKR4 | c.14A>C p.Q5P | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.085); catalogued as COSV51443510; called by muse, mutect2, varscan2
- FCRL5 | c.1495G>T p.G499C | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62520299; called by muse, mutect2, varscan2
- FGD4 | c.1701A>T p.K567N | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV56789416; called by muse, mutect2, varscan2
- GNAL | c.262G>A p.D88N (on ENST00000269162 / NM_001142339.3; = p.D165N on NM_182978.4) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as rs1487090571, COSV52334007; called by muse, mutect2, varscan2
- GPR151 | c.525T>A p.F175L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57042050; called by muse, mutect2, varscan2
- IFT52 | c.1201del p.Q401Rfs*20 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | catalogued as COSV100887669; called by mutect2, pindel, varscan2
- TRPM4 | c.644G>A p.G215D | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV53268818; called by muse, varscan2
- TTN | c.83902C>T p.R27968* (on ENST00000591111; = p.R20544* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV60347470; called by muse, mutect2, varscan2
- UBXN6 | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as COSV56676373; called by muse, mutect2, varscan2
- UNC13B | c.4068C>G p.D1356E | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT tolerated (0.87); PolyPhen benign (0.062); catalogued as COSV65938459; called by muse, mutect2
- D2HGDH | c.318A>G p.P106= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV58323464; called by muse, mutect2, varscan2
- IFFO1 | c.840C>T p.A280= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV60739381; called by muse, mutect2, varscan2
